Somatic mutation profile of tumor specimen ALCH-B3GT-TTP1-A (aliquot ALCH-B3GT-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3GT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.1 years (19,776 days).
Specimen ALCH-B3GT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0c6d60d-45c9-44d6-92d1-4d6a619ae1e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3GT-NB1-A (Blood Derived Normal), aliquot ALCH-B3GT-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56abc7c9-9f39-4a65-9424-78576c11ac64

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 11, Intron 2, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 42/413 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP2A1 | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1442793390; called by muse, mutect2, varscan2
- ATRX | c.4920G>T p.K1640N | Missense Mutation (SNP) | VAF 28/623 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64875521; called by muse, mutect2
- CDH10 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 46/544 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV52593859, COSV52596113; called by muse, mutect2
- COL4A1 | c.2810C>A p.S937Y | Missense Mutation (SNP) | VAF 76/998 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV65432337; called by muse, mutect2
- FLG | c.2109T>A p.S703R | Missense Mutation (SNP) | VAF 103/918 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs766160397; called by muse, mutect2, varscan2
- PCDHGA3 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 31/943 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV53986325; called by muse, mutect2
- TP53 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 38/614 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1555525857, COSV52661319, COSV52679535, COSV53326529; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.52153G>A p.E17385K (on ENST00000591111; = p.E9961K on NM_003319.4) | Missense Mutation (SNP) | VAF 26/474 reads (5%) | PolyPhen probably damaging (0.994); catalogued as COSV100623205; called by muse, mutect2
- WDFY3 | c.2823G>A p.R941= | Splice Region (SNP) | VAF 32/484 reads (7%) | catalogued as COSV99886617; called by muse, mutect2
- XIRP1 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 36/1145 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1168411619, COSV61139075; called by muse, mutect2
- ALLC | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- ANKRD1 | c.208-2A>T p.X70_splice | Splice Site (SNP) | VAF 29/297 reads (10%) | called by muse, mutect2, varscan2
- ARL10 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 35/466 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2
- CA2 | c.192T>G p.H64Q | Missense Mutation (SNP) | VAF 94/791 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CNMD | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 28/810 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTNAP2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 31/542 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2
- DCLK1 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 54/806 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLT1 | c.2924A>G p.K975R | Missense Mutation (SNP) | VAF 28/656 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- GPR158 | c.2042A>C p.E681A | Missense Mutation (SNP) | VAF 21/488 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRHL3 | c.799G>A p.A267T (on ENST00000350501 / NM_198174.3; = p.A272T on NM_021180.3) | Missense Mutation (SNP) | VAF 22/630 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); called by muse, mutect2
- HDAC9 | c.2054C>A p.A685D | Missense Mutation (SNP) | VAF 39/578 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- HS3ST1 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2
- ITPR3 | c.4175C>T p.P1392L | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA0513 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 18/401 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2
- NEGR1 | c.229A>C p.I77L | Missense Mutation (SNP) | VAF 32/676 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR5P2 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2
- POM121L12 | c.620G>T p.R207M | Missense Mutation (SNP) | VAF 27/435 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- PRPF40A | c.1493A>G p.K498R | Missense Mutation (SNP) | VAF 27/600 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- PTPRD | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 24/671 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.584); called by muse, mutect2
- REPIN1 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by mutect2, varscan2
- SIRPG | c.1158G>C p.K386N | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2
- SYNE1 | c.1978A>G p.M660V (on ENST00000367255 / NM_182961.4; = p.M667V on NM_033071.3) | Missense Mutation (SNP) | VAF 34/768 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- THSD7A | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 35/610 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2
- TNKS1BP1 | c.2560A>T p.T854S | Missense Mutation (SNP) | VAF 13/321 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- TNN | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 34/1140 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2
- TRAF6 | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 24/695 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.044); called by muse, mutect2
- ZBTB32 | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2
- ZDHHC13 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2
- ZNF799 | c.1712A>T p.H571L | Missense Mutation (SNP) | VAF 18/353 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.071); called by muse, mutect2
- ARHGAP33 | c.1254G>A p.E418= | Silent (SNP) | VAF 34/494 reads (7%) | called by muse, mutect2
- C16orf72 | c.627C>T p.T209= | Silent (SNP) | VAF 17/380 reads (4%) | called by muse, mutect2
- CACNA1F | c.1206G>T p.R402= | Silent (SNP) | VAF 36/865 reads (4%) | called by muse, mutect2
- FLNC | c.432C>G p.S144= | Silent (SNP) | VAF 70/1127 reads (6%) | called by muse, mutect2
- HCN1 | c.2202G>A p.P734= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1172557328, COSV57518826; called by mutect2, varscan2
- LRP4 | c.2013G>A p.G671= | Silent (SNP) | VAF 23/781 reads (3%) | called by muse, mutect2
- MARK1 | c.2290C>A p.R764= | Silent (SNP) | VAF 62/652 reads (10%) | catalogued as COSV65067361; called by muse, mutect2
- MORN4 | c.366G>T p.L122= | Silent (SNP) | VAF 11/191 reads (6%) | called by muse, mutect2
- MTNR1B | c.558C>A p.R186= | Silent (SNP) | VAF 34/509 reads (7%) | called by muse, mutect2
- PACC1 | c.741C>A p.T247= | Silent (SNP) | VAF 23/508 reads (5%) | called by muse, mutect2
- PKHD1L1 | c.3213G>C p.A1071= | Silent (SNP) | VAF 23/209 reads (11%) | called by muse, mutect2, varscan2
- AC136777.1 | n.296G>T | RNA (SNP) | VAF 34/588 reads (6%) | called by muse, mutect2
- PCDHGA3 | c.2425-66952G>T | Intron (SNP) | VAF 38/514 reads (7%) | called by muse, mutect2
- PCDHGA3 | c.2425-66951C>T | Intron (SNP) | VAF 38/519 reads (7%) | catalogued as rs1487451079, COSV52754916; called by muse, mutect2
